Surgical pathology report (de-identified scan), TCGA case TCGA-31-1946, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Imperial College, specimen TCGA-31-1946-01A (Primary Tumor).

[page 1 of 4]
Consent: [REDACTED]

Specimen Type:

- 1: LEFT OVARY AND TUBE
- 2: UTERUS AND RIGHT OVARY
- 3: OMENTUM
- 4: BIOPSY RIGHT OVARY
- 5: DOUGHNUT
- 6: BOWEL

[REDACTED]
TCGA-31-1946

Clinical Details:

? ovarian tumour.

Macroscopic Description:

- 1) Left ovary and tube: The specimen weighs 102gms and consists of a fallopian tube and ovary measuring 13 x 4 x 4cm in total. The ovary is multinodular and measures 5 x 4 x 4cm. The specimen is received opened and the ovary has a partially solid and partially cystic appearance with no definite papillary structures present on the external surface. The cyst is multiloculated and the largest cystic space measures 5cm in maximum dimension. The inner surface is ragged and contains dirty grey material. The solid area contains a pale brown tumour that appears papillary on the surface – area that was received opened. This solid tumour area measures 7.5 x 5.5 x 5.5cm. The tumour appears to involve the serosal surface of the ovary at multiple foci. No normal ovarian tissue was identified. The fallopian tube is stretched over and compressed by the tumour but the wall does not seem to be invaded by the tumour. Areas of suspicious serosal breaching are inked blue.

BLOCKS: FS1A-B: 1pc in each. FS1C-FS1D – 1pc each
ROT1A-H: Sections from the firm nodular area: 1pc in each.
ROT1J- K: Representative sections from cystic areas: 1pc in each.
ROT1L: Representative sections from cystic areas: 1,2pcs.
ROT1M-P: Representative sections from cystic areas: 1pc in each.

[page 2 of 4]
- 2) Uterus and right ovary: The specimen weighs 106.8gms. The uterus measures 7.5 longitudinally, 5cm transversally and 3.5cm anteroposteriorly. The serosal surface contains fine fibrous adhesions, but no tumour is identified. A rim of vaginal cuff is attached measuring 1.5 x 4.5cm. The endometrium measures 0.1cm and the myometrium measures 1.4cm in maximum thickness. The right fallopian tube measures 6.5cm in length and 0.8cm in diameter. the right ovary is enlarged and multicystic measuring 4.5 x 4.3 x 2.7cm. Some of the cysts show dirty brown material with a small focus of papillary outgrowth. A small area of perforation is present on the serosal surface of one of the cysts measuring 2.2cm in maximum dimension.

Posterior inked blue, anterior yellow.

BLOCKS: 2A: Right parametrium: 1,4pcs.
2B: Left parametrium: 1,2pcs.
2C: Left parametrium: 1,3pcs.
2D: Vaginal cuff: 1,4pcs.
2E-F: Vaginal cuff: 3pcs in each.
2G-H: Cervix: 1pc in each.
2J: Right fallopian tube: 1,3pcs.
2K-N: Right ovary: 1pc in each.
2P-Q: Endomyometrium: 1pc in each.

TCGA-31-1946

- 3) Omentum: A piece of adipose tissue measuring 15 x 5 x 1.6cm. On serial slicing a small firm white nodule is identified measuring 1.5 x 0.5 x 0.5cm.

BLOCKS: 3A: Identified nodule: 1,2pcs.
3B-D: Representative sections: 1pc in each.

- 4) Biopsy right ovary: A single firm piece of white tissue measuring 2 x 1.1 x 0.7cm. Serially sliced.

BLOCKS: 4A: 1,3pcs.

- 5) Doughnut: Two separate pieces of circular tissue measuring 1cm in maximum dimension, the second piece measures 2cm in maximum dimension. Each piece embedded separately.

BLOCKS: 5A-B: 1pc in each.

- 6) Bowel: A segment of intestine measuring 13.2cm in length and 2cm in maximum diameter with attached mesentery measuring 10 x 4.8 x 1.7cm. On the antimesenteric serosal surface there is an area of roughening; this area measures 3.6 x 2.4cm. The mucosa appears macroscopically normal.

BLOCKS: 6A-B: Resection margins: 1pc in each.
6C-D: Lymph nodes: 4pcs in each.
6E: Lymph nodes: 1,2pcs.
6F-K: Representative sections from area of roughening: 1pc in each.
6H: Representative sections of uninvolved tissue: 1,1pc.

[page 3 of 4]
Frozen Section Diagnosis:

FS: Malignant epithelial ovarian carcinoma high grade with some endometrial areas.

TCGA-31-1946

Microscopic Description:

- 1) LEFT OVARY AND TUBE: The ovarian neoplasm is a serous carcinoma, Grade III. The tumour cells are arranged in sheets and tubulopapillary structures. The tumour cells have large vesicular nuclei with prominent nucleoli and pale eosinophilic cytoplasm. The cells express WT1, ER, pgR (very occasional cells) and are negative for p53. The tumour extends to the surface (Block ROTE) and there is vascular invasion (Block ROTB).

There is residual ovarian tissue containing follicular cysts. There is also another distinct larger cyst, which is an endometriotic cyst. The endometriotic cyst wall contains endometrial stroma and is lined by tall columnar epithelium showing ciliated, eosinophilic and mucinous metaplasia (Block ROTH).

The fallopian tube is within normal limits and is not involved by tumour.

- 2) UTERUS, AND RIGHT OVARY: The endometrium is proliferative. Both parametria are free of tumour. The cervix shows active chronic cervicitis. The vaginal cuff is free of tumour.

The right tube is normal.

The right ovary is involved by serous carcinoma. The tumour extends to the surface (Block 2C). Follicular cysts are present in the residual ovarian tissue.

- 3) OMENTUM: An invasive tumour deposit is present in the omentum (macroscopically, 1.5 cm in maximum dimension).
- 4) BIOPSY RIGHT OVARY: This is a piece of tumour tissue extending to the surface of the specimen.
- 5) DOUGHNUTS: This is large bowel wall within normal limits. No tumour deposits are seen.
- 5) BOWEL: This is large bowel showing tumour deposits on the serosal surface which invade into the muscularis propria (Block 6K). The tumour extends to the circumferential margin (serosal surface) of the bowel.

Eleven lymph nodes are identified, one contains metastatic deposits [1/11] (Block 6E).

[page 4 of 4]
Final Diagnosis:

**OVARIES - BILATERAL OVARIAN SEROUS CARCINOMA, GRADE III
WITH DEPOSITS IN THE OMENTUM, LARGE BOWEL WALL AND
MESENTERIC LYMPH NODE.**

Additional Pathologist(s)/BMS(s)

■

TCGA-31-1946

Source: NCI Genomic Data Commons file 9e2e99c4-c041-4848-9384-aa249a0b31e5 (TCGA-31-1946.5EF31A8F-38E7-486B-8EFC-99CD8C1EC06D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).